CCDI case PBCASH — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Bones, joints and articular cartilage of other and unspecified sites.
https://portal.gdc.cancer.gov/cases/c16715fc-64f1-4c74-86f0-4286ad1c921e

Demographics
Sex at birth: male; Vital status: Alive.

Diagnoses (1)
1. Myofibroblastic tumor, NOS: ICD-O-3 morphology code: 8825/1; Tissue or organ of origin: Head, face or neck, NOS; Age at diagnosis: 9.0 years (3,285 days).

Biospecimens (3 samples)
- Sample 0DMN1D: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DMN1U: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DMN26: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
